Gene-level copy-number profile of tumor specimen ALCH-B2WY-TTP1-A from ALCHEMIST case ALCH-B2WY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 78.6 years (28,697 days).
Specimen ALCH-B2WY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8cb28c4b-fa11-499d-b5e0-f4a73d4d573d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2WY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/33ef0bb5-a82b-4fb8-9a34-6a79fe7ea23d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 1: 5,107; copy number 2: 51,771; copy number 3: 1,576; copy number 4: 137; copy number 5: 89; copy number 6: 30; copy number 7: 20; copy number 8: 17; copy number 9: 9; copy number 10: 6; copy number 11: 10; copy number 12: 2; copy number 13: 9; copy number 14: 1; copy number 15: 1; copy number 16: 1; copy number 17: 4; copy number 20: 1; copy number 22: 1; copy number 23: 2; copy number 24: 1; copy number 31: 2; copy number 41: 2; copy number 45: 1; copy number 61: 1; copy number 302: 1.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,059,708–1,069,355, 2 genes: AL390719.1, AL645608.8.
- chr1:1,275,223–1,280,420, 1 gene: LINC01786.
- chr1:1,378,666–1,379,032, 1 gene: NDUFB4P8.
- chr1:1,426,128–1,427,787, 1 gene: TMEM88B.
- chr1:2,632,568–2,636,620, 1 gene (within-gene range 0–11): MMEL1-AS1.
- chr1:2,811,850–2,817,767, 3 genes: AL592464.2, AL592464.3, AL592464.1.
- chr3:9,793,082–9,835,401, 1 gene (within-gene range 0–1): ARPC4-TTLL3.
- chr3:9,812,762–9,813,097, 1 gene (within-gene range 0–1): AC022382.1.
- chr3:10,141,778–10,153,667, 2 genes: VHL, AC034193.1.
- chr3:11,900,011–11,901,245, 1 gene: NUP210P2.
- chr3:47,802,909–47,850,195, 3 genes (within-gene range 0–2): DHX30, AC026318.1, MIR1226.
- chr3:48,561,718–48,563,781, 1 gene (within-gene range 0–1): UCN2.
- chr3:48,856,926–48,898,904, 1 gene: SLC25A20.
- chr3:49,140,086–49,166,331, 2 genes: LAMB2P1, CCDC71.
- chr3:49,177,634–49,191,858, 1 gene: C3orf84.
- chr3:49,412,206–49,416,475, 1 gene (within-gene range 0–1): TCTA.
- chr3:51,662,693–51,704,323, 3 genes (within-gene range 0–2): TEX264, AC099050.1, RNA5SP132.
- chr5:675,826–676,616, 1 gene (within-gene range 0–1): AC026740.1.
- chr5:1,062,896–1,062,974, 1 gene (within-gene range 0–3): MIR4635.
- chr5:154,685,776–154,685,861, 1 gene: MIR1303.
- chr5:171,359,117–171,367,693, 4 genes: RN7SL339P, RPSAP71, SNORA70J, RPL10P8.
- chr5:176,547,433–176,547,726, 1 gene: RN7SL684P.
- chr7:63,367,427–63,422,053, 11 genes: VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2.
- chr7:74,606,913–74,633,884, 2 genes: AC211433.2, AC211433.3.
- chr7:152,749,079–152,757,951, 2 genes: ATP5PBP3, RN7SL845P.
- chr8:12,341,426–12,400,366, 6 genes (within-gene range 0–2): DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A.
- chr8:33,580,210–33,600,023, 2 genes: RN7SL621P, DUSP26.
- chr8:143,684,452–143,713,898, 4 genes (within-gene range 0–1): ZNF707, LINC02878, CCDC166, AC105219.2.
- chr9:136,935,840–136,937,988, 2 genes (within-gene range 0–3): AL807752.1, AL807752.5.
- chr11:32,435,738–32,437,030, 3 genes (within-gene range 0–2): AL049692.6, AL049692.1, AL049692.5.
- chr11:70,646,165–70,647,562, 1 gene (within-gene range 0–2): SHANK2-AS2.
- chr12:121,444,273–121,444,352, 1 gene (within-gene range 0–1): MIR7107.
- chr14:94,674,877–94,675,829, 1 gene: AL049839.1.
- chr19:1,307,401–1,307,719, 1 gene (within-gene range 0–2): RPS15P9.
- chr20:56,601,701–56,602,113, 1 gene: RPS4XP3.
- chr20:56,667,430–56,667,531, 1 gene: RNU6-1146P.
- chr20:62,352,995–62,356,480, 1 gene (within-gene range 0–3): LAMA5-AS1.
- chr20:62,463,497–62,475,995, 1 gene: GATA5.
- chr20:62,544,343–62,551,526, 1 gene (within-gene range 0–2): MIR1-1HG-AS1.
- chr20:62,554,306–62,554,376, 1 gene (within-gene range 0–2): MIR1-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 211 genes in 56 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,137,017–1,197,936, 7 genes, copy number 5: LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1, TTLL10.
- chr1:1,211,340–1,214,153, 1 gene, copy number 45: TNFRSF4.
- chr1:1,249,777–1,251,334, 1 gene, copy number 22: AL162741.1.
- chr1:1,280,436–1,311,677, 4 genes, copy number 10–17 (within-gene range 3–17): SCNN1D, ACAP3, MIR6726, PUSL1.
- chr1:1,324,756–1,375,495, 6 genes, copy number 5–15: CPTP, TAS1R3, DVL1, MIR6808, MXRA8, AURKAIP1.
- chr1:1,401,909–1,422,691, 5 genes, copy number 5–6 (within-gene range 2–6): MRPL20, RN7SL657P, MRPL20-DT, ANKRD65, AL391244.1.
- chr1:1,430,539–1,442,882, 2 genes, copy number 5–61: LINC01770, VWA1.
- chr1:1,512,162–1,540,624, 2 genes, copy number 6–9: ATAD3A, TMEM240.
- chr1:2,555,639–2,569,888, 2 genes, copy number 17–24 (within-gene range 2–24): TNFRSF14, AL139246.2.
- chr1:2,586,491–2,591,469, 1 gene, copy number 8 (within-gene range 3–8): PRXL2B.
- chr1:2,635,976–2,801,717, 3 genes, copy number 11 (within-gene range 0–11): TTC34, AC242022.2, AC242022.1.
- chr1:3,487,246–3,487,627, 1 gene, copy number 7: AL512413.1.
- chr3:48,620,759–48,662,886, 3 genes, copy number 5–11: TMEM89, CELSR3, MIR4793.
- chr7:63,348,861–63,351,774, 2 genes, copy number 6 (within-gene range 1–6): AC006455.5, AC006455.2.
- chr8:37,421,341–38,468,834, 47 genes, copy number 5–11: LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22.
- chr8:143,790,920–143,840,256, 6 genes, copy number 7–12: SCRIB, MIR937, PUF60, AC234917.3, AC234917.1, AC234917.2.
- chr9:136,440,096–136,780,218, 23 genes, copy number 5–41: SEC16A, C9orf163, NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1, LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2, DIPK1B, SNORA17B, SNORA17B, AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3.
- chr9:136,844,415–136,860,799, 3 genes, copy number 10 (within-gene range 3–10): AJM1, PHPT1, MAMDC4.
- chr12:132,424,504–132,425,208, 1 gene, copy number 31: AC148476.1.
- chr14:105,486,317–105,601,728, 8 genes, copy number 5–13: CRIP1, AL928654.3, TEDC1, TMEM121, ATP5MC1P1, ELK2BP, IGHA2, IGHE.
- chr14:105,621,116–105,621,180, 1 gene, copy number 5: MIR8071-1.
- chr16:649,311–667,833, 2 genes, copy number 9 (within-gene range 2–9): WDR90, AL022341.2.
- chr16:678,504–692,554, 6 genes, copy number 13 (within-gene range 1–13): LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1.
- chr16:975,761–1,000,926, 3 genes, copy number 5–6 (within-gene range 3–6): CEROX1, SOX8, AC009041.1.
- chr16:88,382,959–88,440,757, 1 gene, copy number 14: ZNF469.
- chr16:88,643,289–88,663,161, 2 genes, copy number 9–16: CYBA, MVD.
- chr16:88,696,499–88,866,660, 15 genes, copy number 5: RNF166, AC138028.3, CTU2, AC138028.6, PIEZO1, MIR4722, AC138028.4, AC138028.2, AC138028.5, AC138028.1, CDT1, APRT, GALNS, TRAPPC2L, PABPN1L.
- chr16:89,046,172–89,052,966, 1 gene, copy number 8: AC135782.1.
- chr16:89,906,157–89,918,233, 1 gene, copy number 7 (within-gene range 1–7): AC092143.3.
- chr17:81,165,507–81,183,166, 1 gene, copy number 5 (within-gene range 2–5): PVALEF.
- chr17:83,104,255–83,106,910, 1 gene, copy number 5: AC144831.1.
- chr17:83,220,527–83,240,804, 2 genes, copy number 5: AC139099.1, RPL23AP87.
- chr19:639,879–644,371, 1 gene, copy number 6: FGF22.
- chr19:676,392–683,392, 1 gene, copy number 9: FSTL3.
- chr19:1,103,926–1,174,268, 2 genes, copy number 5–7: GPX4, SBNO2.
- chr19:1,228,287–1,239,522, 2 genes, copy number 8 (within-gene range 4–8): CBARP, AC004221.1.
- chr19:1,248,553–1,279,244, 4 genes, copy number 9: MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:2,163,933–2,355,095, 17 genes, copy number 5 (within-gene range 2–5): DOT1L, AC004490.1, PLEKHJ1, MIR1227, MIR6789, SF3A2, AMH, MIR4321, JSRP1, OAZ1, AC005258.1, PEAK3, LINGO3, AC104530.1, AC005258.2, LSM7, SPPL2B.
- chr20:62,388,632–62,407,285, 2 genes, copy number 6: CABLES2, AL121832.3.
- chr20:63,400,208–63,472,677, 2 genes, copy number 5 (within-gene range 4–15): KCNQ2, AL353658.1.

Autosomal genes at a single copy (total copy number 1): 2,251. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
